TCGA case TCGA-GS-A9TY — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Fundacio Clinic per a la Recerca Biomedica. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e9437f0-a4ed-475c-ab0e-bf1431c70a90

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Spain; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of axilla or arm; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2005; AJCC staging edition: 6th; Ann Arbor clinical stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,616 days (7.2 years); Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Axillary.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Consistent pathology review: Yes; Greatest tumor dimension: 1 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 28 days; Number of cycles: 6; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Pleura, NOS. Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: 2,616 days (7.2 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 2,616 (post initial treatment): Disease response: Tumor Free; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 2,616 days (7.2 years).
- Days to follow up: 2,616 days (7.2 years); Disease response: With Tumor.
- Imaging type: PET; Imaging result: Negative; Timepoint: Within 2 Months After Completion of First-Course Treatment.
- ECOG performance status: 1.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 (PCR): Normal.
- BCL6 (IHC): Positive.
- CD10 (IHC): Negative.
- CD20 (IHC): Positive.
- CD5 (IHC): Negative.
- IRF4 (IHC): Negative.
- Immunoglobulin, Cytoplasmic (IHC): Equivocal.
- TP53 (IHC): Positive.
- Lactate Dehydrogenase 288 IU [Blood test normal range upper: 450].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 153 cm; BMI: 32.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GS-A9TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-GS-A9TY-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-GS-A9TY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GS-A9TY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 0; Bone marrow biopsy performed: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary.
- Tests performed: LDH level: 288; Mib 1 positive percent range: 51 - 75%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: P53 >20%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: Cytoplasmic Ig; Immunophenotypic analysis method: Immunohistochemistry; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: BCL2.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Drug treatment 1: Pharmaceutical therapy drug name: ciclofosfamida; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 2: Pharmaceutical therapy drug name: prednisona; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 4: Pharmaceutical therapy drug name: vincristina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,333 days; disease-specific survival: no event (censored), 3,333 days; disease-free interval: event (new tumor event after initially disease-free), 3,255 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,255 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GS-A9TY-01A-11D-A38W-01): tumor purity 0.8, ploidy 3.2, whole-genome doublings 1.
